Somatic mutation profile of tumor specimen 0DP4Q3 from CCDI case PBCCXW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.3 years (6,321 days).
Specimen 0DP4Q3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e138756c-4d03-4d49-99b7-b2350dcd7306.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP4P0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80766259-b47f-4edb-8417-ecd56e4f22d1

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCER2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | catalogued as rs928697303; called by muse, mutect2
- PGM5 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781901814, COSV67167136; called by muse, mutect2, varscan2
- SLC47A1 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs1453649762; called by muse, mutect2, varscan2
- ZDBF2 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs745571949, COSV65621296; called by muse, mutect2
- PRG4 | c.3720T>C p.T1240= | Silent (SNP) | VAF 20/335 reads (6%) | catalogued as rs757584066; called by muse, mutect2
- SMARCB1 | c.363-2242C>T | Intron (SNP) | VAF 39/270 reads (14%) | catalogued as CM991144, COSV54093065; called by muse, mutect2, varscan2
